Surgical pathology report (de-identified scan), TCGA case TCGA-O9-A75Z, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Saint Mary's Health Care, specimen TCGA-O9-A75Z-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site ④ Kidney NOS
C64.9
JW 8/21/13

PROCEDURE

Left robotic partial nephrectomy

HISTORY

Left renal mass

GROSS

Received fresh, labeled "left renal mass," is a 3 x 3 x 3 cm, 12-gram partial nephrectomy. The surgical margin is marked with black ink. The loosely attached fat is marked with green ink. Cut section shows a 2.5 x 2.5 x 2 cm yellow to hemorrhagic mass. The mass is well-circumscribed and is contained within the renal capsule. It is 0.1 cm to the black-inked surgical margin and 0.3 cm to the green-inked circumferential surface. A sample of the tissue is submitted for research studies per protocol. Tissue submitted for the TCGA research study. Representative sections submitted in five cassettes.

Sections are taken as follows:

- 1-2 as tumor with green-inked circumferential surface
- 3-5 as tumor with black-inked surgical margin

Total time in 10% neutral buffered formalin from collection through processing: 34.5 hours. Total cold ischemia time: 15 minutes.

DIAGNOSIS

KIDNEY CANCER PROFILE

SPECIMEN TYPE: PARTIAL NEPHRECTOMY (LEFT).

CLINICAL/WORKING STAGE: N/A

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

TISSUE COLD ISCHEMIA TIME: 15 MINUTES.

TISSUE DURATION IN 10 PERCENT NEUTRAL BUFFERED FORMALIN: 34.5 HOURS.

TUMOR SITE: MIDDLE POLE.

FOCALITY: UNIFOCAL.

TUMOR SIZE: 2.5 x 2.5 CM

HISTOLOGIC TYPE: PAPILLARY RENAL CELL CARCINOMA.

SARCOMATOID FEATURES: ABSENT.

HISTOLOGIC GRADE: N/A

EXTENT OF INVASION: TUMOR CONFINED TO RENAL PARENCHYMA.

LYMPH-VASCULAR INVASION: ABSENT.

COAGULATIVE NECROSIS OF TUMOR: NEGATIVE.

MARGINS: RENAL PARENCHYMAL MARGIN INVOLVED BY TUMOR ALONG A 5 MM LINEAR DIMENSION. REMAINING MARGINS FREE OF TUMOR.

LYMPH NODES: NO LYMPH NODES PRESENT.

PATHOLOGIC FINDINGS IN NON-NEOPLASTIC KIDNEY: ONLY A SMALL RIM OF NORMAL PARENCHYMA IS PRESENT, WHICH SHOWS MILD INTERSTITIAL NEPHRITIS LIKELY RELATED TO ADJACENT TUMOR.

DISTANT METASTASIS: NOT APPLICABLE.

CANCER STAGE: pT1a, pNX

Note: Immunostains demonstrate that the tumor cells are positive for CK7 and racemase, but negative for CD10. The results support the diagnosis.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

88307, 88342 X3

(Electronic Signature)

Completed Action List:

* Order by

on

Type:

Surg Path Final Report

Date:

Status:

Auth (Verified)

Title:

SURG PATH FINAL REPORT

Encounter info:

Contributor system:

Printed by:

Printed on:

Page 3 of 3
(End of Report)

HPA Discrepancy		☒

Source: NCI Genomic Data Commons file 8242d9ab-6658-4ddd-a92b-253cdbf034c9 (TCGA-O9-A75Z.A55C12D4-B4C2-4C04-8BE5-18B003B418C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).